CPTAC case C3N-01814 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a58efbf-2708-4f13-87ab-253d7d67ef52

Demographics
Sex at birth: female; Race: asian; Year of birth: 1968; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 48.8 years (17,813 days); Year of diagnosis: 2017; Last known disease status: Tumor free; Days to last known disease status: 383 days (1.0 years); Days to last follow up: 383 days (1.0 years).
   Pathology details: Greatest tumor dimension: 7 cm.

Follow-up (2 entries)
- Days to follow up: 383 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 3.
- Days to follow up: 383 days (1.0 years); Disease response: Complete Response; Karnofsky performance status: 70; ECOG performance status: 3.

Other clinical attributes
- Weight: 52 kg; Height: 153 cm; BMI: 22.21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (10 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01814-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 100 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01814-21: Section location: Left Hemisphere; Percent tumor nuclei: 90; Percent necrosis: 3.
- Sample C3N-01814-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 100 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01814-22: Section location: Left Hemisphere; Percent tumor nuclei: 90; Percent necrosis: 3.
- Sample C3N-01814-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 100 mg.
- Samples C3N-01814-31, C3N-01814-32, C3N-01814-72, C3N-01814-73, C3N-01814-74, C3N-01814-75 (6 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01814-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
